Somatic mutation profile of tumor specimen 0DFJKU from CCDI case PBBSGU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,448 days).
Specimen 0DFJKU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2932ef3-ce3c-414b-8539-1e3a15cfc2a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJJ6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fc6e931-90cf-4e49-9a7b-1f94fdc3d8e4

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CST6 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 132/411 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs746561607; called by muse, mutect2, varscan2
- KIAA1522 | c.1327C>T p.R443C (on ENST00000373480 / NM_001198972.2; = p.R502C on NM_020888.3) | Missense Mutation (SNP) | VAF 59/888 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs766963606; called by muse, mutect2
- PDGFRA | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 5793/6460 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- POTEE | c.2786C>T p.T929M | Missense Mutation (SNP) | VAF 159/1802 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1335497622; called by muse, mutect2
- POTEI | c.2860T>C p.W954R | Missense Mutation (SNP) | VAF 135/831 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1180587103; called by muse, mutect2
- FOLH1 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 295/441 reads (67%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 60/1565 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- NPRL3 | c.1351+8C>A | Splice Region (SNP) | VAF 169/404 reads (42%) | called by muse, mutect2, varscan2
- SMIM6 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 317/740 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TMEM132E | c.901T>A p.L301M (on ENST00000321639; = p.L391M on NM_001304438.2) | Missense Mutation (SNP) | VAF 269/788 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- USP29 | c.2691C>G p.N897K | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADGRF3 | c.390G>A p.L130= (on ENST00000311519 / NM_001145168.1; = p.L71= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 374/1292 reads (29%) | catalogued as rs1332133054, COSV100274847; called by muse, mutect2, varscan2
- ATF7 | c.48+95G>A | Intron (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
